Gene-level copy-number profile of tumor specimen TCGA-12-0829-01A from TCGA case TCGA-12-0829, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 75.2 years (27,471 days).
Specimen TCGA-12-0829-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.f7953d53-7430-45d2-8266-802f134526c8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-12-0829-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7f1cc4c1-f3cc-4626-9d90-3193d2a542de

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 69; copy number 1: 6,233; copy number 2: 45,338; copy number 3: 7,796; copy number 4: 19; copy number 5: 34; copy number 6: 141; copy number 7: 35; copy number 8: 51; copy number 9: 12; copy number 11: 83; copy number 23: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-12-0829-01A-01D-0384-01): tumor purity 0.42, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 69 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,926,094–22,455,740, 69 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 365 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:203,861,599–205,602,918, 55 genes, copy number 6 (within-gene range 2–6): SNRPE, KRT8P29, HSPE1P6, CBX1P3, AC096645.1, LINC00303, AL592146.2, SOX13, AL592146.1, ETNK2, ERLNC1, REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3, LRRN2, AL512306.2, AL161793.1, RNA5SP75, AL161793.2, AC096675.1, NFASC, AL391822.1, CNTN2, TMEM81, RBBP5, AL583832.1, AC093422.2, DSTYK, AC093422.1, TMCC2, TMCC2-AS1, NUAK2, KLHDC8A, SNRPGP10, LEMD1-AS1, LEMD1, BLACAT1, MIR135B, LEMD1-DT, CDK18, RNU2-19P, MFSD4A.
- chr3:173,910,498–173,920,796, 1 gene, copy number 9: NLGN1-AS1.
- chr3:174,302,944–175,810,548, 11 genes, copy number 9 (within-gene range 3–9): ANAPC15P2, AC069218.1, NAALADL2, RN7SKP40, EEF1B2P8, NAALADL2-AS3, NAALADL2-AS2, MIR4789, RNU6-1233P, AC008180.3, RNU4-91P.
- chr3:176,763,233–184,293,031, 160 genes, copy number 5–11 (within-gene range 4–11) (broad region; genes not listed).
- chr3:184,812,143–185,938,103, 17 genes, copy number 6 (within-gene range 4–6): VPS8, C3orf70, EHHADH-AS1, EHHADH, EIF2S2P2, MIR5588, MAP3K13, RPL4P4, TMEM41A, AC099661.1, LIPH, SENP2, AC133473.1, IGF2BP2, IGF2BP2-AS1, MIR548AQ, TRA2B.
- chr3:187,120,948–190,167,651, 37 genes, copy number 5–7 (within-gene range 3–7): RPL39L, AC007920.1, RTP1, MASP1, AC007920.2, RTP4, AC068299.2, AC068299.1, LINC02041, SST, RTP2, AC072022.1, BCL6, AC072022.2, AC108681.1, AC068295.1, LINC01991, AC092941.1, AC092941.2, AC022498.1, LPP-AS2, LPP, FLJ42393, LPP-AS1, MIR28, TPRG1-AS1, TPRG1, AC009319.1, TPRG1-AS2, TP63, AC078809.1, MIR944, P3H2, MTAPP2, P3H2-AS1, RNU6-1109P, NMNAT1P3.
- chr7:54,759,348–55,433,742, 9 genes, copy number 23: SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2.
- chr11:121,024,072–121,313,410, 6 genes, copy number 5: TBCEL, TBCEL-TECTA, TECTA, AP001124.1, RPS4XP12, SC5D.
- chr15:70,047,790–72,798,199, 69 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,852. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
